Surgical pathology report (de-identified scan), TCGA case TCGA-3Q-A9WF, project TCGA-THYM (Thymoma), tissue source site Greenville Health Systems, specimen TCGA-3Q-A9WF-01A (Primary Tumor).

[page 1 of 2]
PATHOLOGY EXAMINATION

ACCESSION #

PATIENT NAME:

COLLECTED:

CLIENT:

RECEIVED:

PHYSICIAN:

REPORTED:

GENDER:

DOB:

ADDITIONAL:

NO ADDITIONAL PHYSICIANS

LOCATION:

ACCOUNT #:

COPY TO/NOTES:

ROOM/BED:

Page 1 of 2

SPECIMEN(S) RECEIVED:

A: Thymus, thymectomy stitch to right superior horn

CLINICAL DATA/HISTORY:

Tissue banking.

FINAL PATHOLOGIC DIAGNOSIS:

"THYMUS":

- SPECIMEN: THYMUS.
- PROCEDURE: THYMECTOMY.
- SPECIMEN INTEGRITY: INTACT.
- SPECIMEN WEIGHT: 97 GRAMS.
- TUMOR SIZE: 3.5 X 3 X 2.5 CM (GROSS MEASUREMENT).
- HISTOLOGIC TYPE: TYPE B2 THYMOMA.
- TUMOR EXTENSION: NOT IDENTIFIED.
- MARGINS: UNINVOLVED BY TUMOR.
- DISTANCE FROM CLOSEST MARGIN: LESS THAN 1 MM. (ANTERIOR).
- TREATMENT EFFECT: NOT APPLICABLE.
- LYMPH VASCULAR INVASION: NOT IDENTIFIED.
- REGIONAL LYMPH NODES: ONE INTRATHYMIC LYMPH NODE EXAMINED, NEGATIVE FOR MALIGNANCY (0/1).
- PATHOLOGIC STAGING: STAGE I.
- IMPLANT / DISTANT METASTASES: NOT IDENTIFIED.
- SEE COMMENT.

ICD-O-3

Thymoma, type B2 8584/3

Site: thymus C37.9

fw
1/17/14

COMMENT:

Clinical, radiologic, and surgical correlation are recommended. See flow cytometry

ELECTRONICALLY SIGNED OUT

GROSS DESCRIPTION:

Thymus, thymectomy stitch to right superior horn: Received fresh for tissue banking labeled "Thymus, stitch to right superior horn", is a 97 gram thymus which measures 16 x 7 x 1.5 cm and displays a stitch designating the right superior horn. The specimen is inked as follows: posterior black, anterior right superior horn red, anterior left superior horn orange, anterior left inferior horn yellow, anterior right inferior horn green.

The right superior horn displays a 3.5 x 3.0 x 2.5 cm well-defined, easily palpable, pink-tan, smooth, glistening, homogeneous mass which resembles fish flesh and comes to within 0.1 cm of the red inked anterior right superior horn margin and 0.2 cm of the black inked posterior margin. This appears well-encapsulated. Capsular penetration is not noted on gross examination. A representative section of the mass (as well as non-neoplastic tissue) is submitted for tissue banking. Representative tissue from the mass is placed in solution for possible

[page 2 of 2]
flow and a representative section of the mass is also placed in B plus fixative. Two touch preparations of the mass (one H&E, one Wright-Giemsa) are performed. Representative sections of the mass are submitted.

The remaining specimen is serially sectioned to reveal fatty, smooth cut surfaces. No additional mass lesions are identified.

Representative sections are submitted as follows: A1-A2 right superior horn mass to include red inked anterior right superior horn margin. A3 right superior horn mass to include black inked posterior margin. A4 right superior horn mass, following B plus fixation. A5 right superior horn, random sections. A6 left superior horn, random sections. A7 left inferior horn, random sections. A8 right inferior horn, random sections. Diagram drawn.

MICROSCOPIC DESCRIPTION:

Thymic tissue is represented. The mass is comprised of an admixture of small and large lymphocytes with epithelial cells noted. CD3 and CD20 stains show the lymphoid cells to be predominantly CD3 positive T cells. A Pankeratin stain highlights the epithelial cells. Admixed Hassall's corpuscles are seen. An intrathymic lymph node is present in slide A6. No definitive capsular penetration is seen.

Source: NCI Genomic Data Commons file bb0c9103-cbf1-4d9f-aff9-ab4aecb3207c (TCGA-3Q-A9WF.9B8C858A-F093-43E8-8741-A5506A4D71EA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).